Somatic mutation profile of tumor specimen TCGA-V4-A9F7-01A (aliquot TCGA-V4-A9F7-01A-11D-A39W-08) from TCGA case TCGA-V4-A9F7, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 78.9 years (28,822 days).
Specimen TCGA-V4-A9F7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a331cdee-9c1f-4a68-b4e2-e120faaa9c2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9F7-10A (Blood Derived Normal), aliquot TCGA-V4-A9F7-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ca91cd0-6aaa-4dc8-bd4b-a60e5326c577

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Nonsense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 17/78 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63309310, COSV63309316; called by muse, mutect2, varscan2
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CEP131 | c.2363C>T p.A788V (on ENST00000269392 / NM_001319228.2; = p.A785V on NM_014984.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as rs754140951; called by muse, mutect2, varscan2
- DNAH11 | c.1564A>G p.T522A | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs186667584; called by muse, mutect2, varscan2
- NHS | c.1780G>A p.V594I | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as rs767956070, COSV66272541, COSV66282606; called by muse, mutect2, varscan2
- PTPRD | c.4270G>A p.A1424T | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1564475749, COSV100643528, COSV61970813; called by muse, mutect2
- XRCC3 | c.524T>C p.F175S | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1419229375, COSV100573113; called by muse, mutect2, varscan2
- COL2A1 | c.2792C>A p.A931D | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.64); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- GNB1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- HHEX | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- OR51L1 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.034); called by muse, mutect2
- ZC3H7A | c.2611C>T p.Q871* | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | called by muse, mutect2, varscan2
- BRD1 | c.1290A>G p.A430= | Silent (SNP) | VAF 74/133 reads (56%) | catalogued as COSV53455138; called by muse, mutect2, varscan2
- ZNF628 | c.624C>T p.L208= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs747118126; called by muse, varscan2
